Somatic mutation profile of tumor specimen TCGA-DX-A8BG-01A (aliquot TCGA-DX-A8BG-01A-12D-A417-09) from TCGA case TCGA-DX-A8BG, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 83.0 years (30,333 days).
Specimen TCGA-DX-A8BG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e70f0c6-7334-4b7b-9e6a-61d935f13381.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A8BG-10B (Blood Derived Normal), aliquot TCGA-DX-A8BG-10B-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73d90e4b-ce22-4a42-8945-2bc86e01c9b1

The open-access MAF lists 61 somatic variants for this specimen: 41 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 18, Nonsense Mutation 2, Intron 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1389+1G>A p.X463_splice | Splice Site (SNP) | VAF 86/267 reads (32%) | hotspot (GDC flag); catalogued as CS030554, CS040291, COSV57305792, COSV57317132, COSV99925881; called by muse, mutect2, varscan2
- AASS | c.1759G>T p.E587* | Nonsense Mutation (SNP) | VAF 6/77 reads (8%) | catalogued as COSV100741849; called by muse, mutect2
- AASS | c.1758G>T p.L586F | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV100741850; called by muse, mutect2
- ACACB | c.5160C>A p.F1720L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100623119; called by muse, mutect2
- ACSF2 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.721); catalogued as rs1191122727, COSV51971644; called by muse, mutect2, varscan2
- ADCK5 | c.1076C>G p.S359W | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58234157; called by muse, varscan2
- CAPN13 | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as COSV99700678; called by muse, mutect2
- CDKL5 | c.920C>G p.P307R | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101184411; called by muse, mutect2, varscan2
- CELSR2 | c.2824C>T p.R942W | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99604452; called by muse, mutect2
- CHCHD6 | c.547A>G p.K183E | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV99336722; called by muse, mutect2, varscan2
- CHD3 | c.4670C>G p.T1557S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.373); catalogued as COSV100391454; called by muse, mutect2, varscan2
- CHMP7 | c.793T>A p.C265S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.76); catalogued as COSV100500682; called by muse, mutect2, varscan2
- CNTNAP3 | c.2909G>A p.R970H | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs528416073, COSV99905323; called by muse, mutect2, varscan2
- CSF2RB | c.2402C>G p.A801G | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV53256244, COSV99454225; called by muse, mutect2, varscan2
- DPY19L4 | c.2010G>T p.M670I | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV101363408; called by muse, mutect2, varscan2
- FGG | c.1167T>G p.Y389* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as COSV100271987; called by muse, mutect2, varscan2
- FMN2 | c.4339T>A p.F1447I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100146545; called by muse, mutect2, varscan2
- HBG2 | c.314A>G p.K105R | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100400679; called by muse, varscan2
- HOOK1 | c.533A>C p.Q178P | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.317); catalogued as COSV100969173; called by muse, mutect2, varscan2
- KLHL30 | c.1089G>A p.M363I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1235390072, COSV59979548; called by muse, mutect2, varscan2
- KRT33B | c.593T>A p.V198D | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99290734; called by muse, mutect2
- KRT71 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as rs150480717; called by muse, mutect2, varscan2
- MYH7 | c.2055C>A p.D685E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as COSV100806391; called by muse, mutect2, varscan2
- NAALAD2 | c.347A>T p.N116I | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100428660; called by muse, mutect2, varscan2
- NHSL2 | c.974C>G p.S325C (on ENST00000510661; = p.S691C on NM_001013627.2) | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as COSV101030244; called by muse, mutect2
- NR1I3 | c.500T>C p.F167S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as COSV100915808; called by muse, mutect2, varscan2
- PAX5 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.973); catalogued as rs984035588, COSV63905826; called by muse, mutect2
- POU2F1 | c.1505C>T p.S502F (on ENST00000541643 / NM_001365848.1; = p.S525F on NM_002697.4) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.276); catalogued as COSV99611640; called by muse, mutect2
- PRRC2A | c.5371G>A p.E1791K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV99277383; called by muse, varscan2
- PRRC2A | c.6349G>A p.A2117T | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV99277385; called by muse, varscan2
- PSME4 | c.1610G>A p.C537Y | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV101122590; called by muse, mutect2, varscan2
- PTPRZ1 | c.538T>C p.S180P | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101100548; called by muse, mutect2
- SHANK2 | c.3220G>A p.V1074I | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.379); catalogued as rs782391344, COSV99571533; called by muse, mutect2
- SHROOM2 | c.3798G>C p.Q1266H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as COSV101098912; called by muse, mutect2, varscan2
- SLC25A10 | c.253G>T p.V85L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV58970304; called by muse, mutect2
- TCHHL1 | c.189C>G p.D63E | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV100916574; called by muse, mutect2
- TIPRL | c.659A>G p.K220R | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs753509670, COSV100893418; called by muse, mutect2, varscan2
- UBR4 | c.9872A>T p.Q3291L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100921386; called by muse, mutect2, varscan2
- ZNF284 | c.1513C>T p.H505Y | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV101399044; called by muse, mutect2, varscan2
- ZNF534 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99990006; called by muse, mutect2
- ZNF74 | c.656C>A p.A219E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100677524; called by muse, mutect2, varscan2
- ADGRG5 | c.705C>T p.L235= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV61084956; called by muse, mutect2, varscan2
- ARID3B | c.945C>T p.L315= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100654696; called by muse, mutect2, varscan2
- ASXL3 | c.2868T>C p.S956= | Silent (SNP) | VAF 4/65 reads (6%) | catalogued as rs1036083820, COSV99325852; called by muse, mutect2
- ATP2C2 | c.2109C>T p.A703= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV52299319, COSV99298429; called by muse, mutect2
- CARMIL2 | c.2226G>A p.E742= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs768273296, COSV100576174; called by muse, mutect2, varscan2
- CEACAM8 | c.627C>T p.D209= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as rs749937078, COSV54990003; called by muse, mutect2, varscan2
- CHRNA7 | c.232C>T p.L78= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100181494; called by muse, mutect2, varscan2
- DENND1A | c.2148G>A p.P716= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs373221297; called by muse, mutect2, varscan2
- DNAJB11 | c.237T>C p.D79= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as COSV99408690; called by muse, mutect2
- GRIN2A | c.180G>A p.A60= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV58023079; called by muse, mutect2, varscan2
- KRTAP4-4 | c.438C>T p.C146= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs772417468, COSV101180570; called by muse, mutect2
- MYH8 | c.1695C>T p.N565= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as COSV101238554, COSV67970121; called by muse, mutect2
- NUP188 | c.2811G>T p.L937= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV101001442, COSV65365293; called by muse, mutect2
- OTOP1 | c.1374C>A p.I458= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV56393945, COSV99587915; called by muse, mutect2
- PDX1 | c.576C>A p.I192= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV101124105; called by muse, mutect2, varscan2
- PLA2G2F | c.525C>A p.G175= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs1326435847, COSV100907920; called by muse, mutect2, varscan2
- PRRC2A | c.6417G>T p.R2139= | Silent (SNP) | VAF 15/143 reads (10%) | catalogued as COSV99277386; called by muse, varscan2
- SPATS1 | c.669A>C p.S223= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV99913557; called by muse, mutect2, varscan2
- GCNT2 | c.926-34780C>A | Intron (SNP) | VAF 13/50 reads (26%) | catalogued as COSV99399460; called by muse, mutect2, varscan2
- SSPOP | n.9650T>A | RNA (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100947778; called by muse, mutect2, varscan2
